Somatic mutation profile of tumor specimen 0DGZFH from CCDI case PBBTXA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Angiomyosarcoma; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 14.8 years (5,407 days).
Specimen 0DGZFH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c2404ee9-9e78-49f9-bbdd-ac9672f12044.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DGYZ2 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a3f72056-8122-4494-9489-18680a1c2fc2

The open-access MAF lists 29 somatic variants for this specimen: 21 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 6, Splice Site 4, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACACB | c.3716G>A p.R1239Q | Missense Mutation (SNP) | VAF 68/321 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as rs965439360; called by muse, mutect2, varscan2
- BCAS3 | c.1486+1G>T p.X496_splice | Splice Site (SNP) | VAF 40/206 reads (19%) | catalogued as rs1207929877; called by mutect2, varscan2
- CFAP46 | c.1714G>A p.E572K | Missense Mutation (SNP) | VAF 71/270 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as rs915496495; called by muse, mutect2, varscan2
- FBXO17 | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 217/354 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766521267, COSV53069556; called by muse, mutect2, varscan2
- GRM8 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 76/245 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs199601760; called by muse, mutect2, varscan2
- GSG1L | c.527C>T p.A176V (on ENST00000447459 / NM_001109763.2; = p.A21V on NM_144675.2) | Missense Mutation (SNP) | VAF 120/384 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as rs141366433; called by muse, mutect2, varscan2
- HEATR6 | c.1735C>T p.R579C | Missense Mutation (SNP) | VAF 217/350 reads (62%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.741); catalogued as rs745378964; called by muse, mutect2, varscan2
- IGF2BP2 | c.1321G>A p.A441T | Missense Mutation (SNP) | VAF 76/294 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.889); catalogued as rs753600987, COSV60487672; called by muse, mutect2, varscan2
- KLF15 | c.1237C>T p.R413C | Missense Mutation (SNP) | VAF 111/218 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as rs1397851303; called by muse, mutect2, varscan2
- MINK1 | c.2062C>T p.R688W | Missense Mutation (SNP) | VAF 85/388 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as rs1286283885, COSV61789415; called by muse, mutect2, varscan2
- PRPF4 | c.296A>G p.N99S (on ENST00000374198 / NM_001322267.2; = p.N100S on NM_004697.5) | Missense Mutation (SNP) | VAF 67/244 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0.079); catalogued as rs772800358; called by muse, mutect2, varscan2
- ST6GAL2 | c.1381C>T p.R461W | Missense Mutation (SNP) | VAF 60/215 reads (28%) | PolyPhen probably damaging (1); catalogued as rs763640071; called by muse, mutect2, varscan2
- TP53 | c.672G>T p.E224D | Missense Mutation (SNP) | VAF 70/82 reads (85%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as rs267605076, CS100446, COSV52678333, COSV52681634, COSV52721244; called by mutect2, varscan2
- ACSL4 | c.802A>G p.T268A (on ENST00000340800 / NM_022977.2; = p.T227A on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/187 reads (24%) | SIFT tolerated (0.75); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KCNT2 | c.2348+1G>A p.X783_splice | Splice Site (SNP) | VAF 87/204 reads (43%) | called by muse, mutect2, varscan2
- LGR4 | c.617+2T>C p.X206_splice | Splice Site (SNP) | VAF 43/164 reads (26%) | called by muse, mutect2
- OR2W1 | c.440T>C p.M147T | Missense Mutation (SNP) | VAF 74/200 reads (37%) | SIFT tolerated (0.52); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OXNAD1 | c.157A>G p.R53G | Missense Mutation (SNP) | VAF 45/270 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- SLC4A4 | c.1498-1G>T p.X500_splice (on ENST00000264485 / NM_001098484.3; = p.X456_splice on NM_003759.4) | Splice Site (SNP) | VAF 12/204 reads (6%) | called by muse, mutect2
- SUOX | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 51/220 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- UBA1 | c.2899G>C p.G967R | Missense Mutation (SNP) | VAF 60/313 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.98); called by mutect2, varscan2
- AC104389.6 | c.486C>T p.A162= | Silent (SNP) | VAF 96/370 reads (26%) | called by muse, mutect2, varscan2
- AVL9 | c.1272C>T p.V424= | Silent (SNP) | VAF 80/291 reads (27%) | called by muse, mutect2, varscan2
- INHA | c.810C>T p.S270= | Silent (SNP) | VAF 114/437 reads (26%) | called by muse, mutect2, varscan2
- IVL | c.1362G>A p.E454= | Silent (SNP) | VAF 57/359 reads (16%) | called by muse, mutect2, varscan2
- MOXD1 | c.1818C>T p.C606= | Silent (SNP) | VAF 70/370 reads (19%) | catalogued as rs748193134, COSV60945592; called by muse, mutect2, varscan2
- TUBB4A | c.1200C>T p.G400= | Silent (SNP) | VAF 110/991 reads (11%) | catalogued as rs149366909; called by muse, mutect2, varscan2
- DCHS2 | n.2153C>T | RNA (SNP) | VAF 68/244 reads (28%) | catalogued as rs770720107; called by muse, mutect2, varscan2
- RBBP7 | c.16+361G>T | Intron (SNP) | VAF 44/91 reads (48%) | called by muse, mutect2, varscan2
